Somatic mutation profile of tumor specimen MMRF_2826_1_BM_CD138pos (aliquot MMRF_2826_1_BM_CD138pos_T1_KHS5U_L16554) from MMRF case MMRF_2826, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2826_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00edb542-5d26-4182-a487-ee1f993904ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2826_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2826_1_PB_WBC_C2_KHS5U_L16597; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2e887bb-bd54-4dbe-8e56-27f710834a56

The open-access MAF lists 187 somatic variants for this specimen: 92 protein-altering or splice-affecting, 21 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 43, Silent 21, Intron 13, 5'UTR 7, 5'Flank 6, Nonsense Mutation 6, Frame Shift Del 4, 3'Flank 3, RNA 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 70/160 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- ASIC3 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as rs200391606; called by muse, mutect2, varscan2
- COL12A1 | c.3544G>A p.V1182I | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as rs1294234005; called by muse, mutect2, varscan2
- DNAH6 | c.3472C>A p.P1158T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs756299384; called by muse, mutect2, varscan2
- DNAH9 | c.12743G>C p.R4248P | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52351438; called by muse, mutect2, varscan2
- FAT1 | c.7765G>A p.D2589N | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV101499396; called by muse, mutect2
- FSD2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV58010567; called by muse, mutect2, varscan2
- FUT5 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 13/380 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1422586533; called by muse, mutect2
- GAB1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770936099, COSV53757990; called by muse, mutect2, varscan2
- GEMIN5 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV53558235; called by muse, mutect2
- GPR26 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs963755360, COSV52933418; called by muse, mutect2, varscan2
- HK2 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs62642507; called by muse, mutect2, varscan2
- IGLV3-1 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181169560; called by muse, varscan2
- IGLV3-1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs548457166; called by muse, varscan2
- IGLV3-1 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs371563415; called by muse, varscan2
- KIAA1549L | c.4483C>T p.R1495* (on ENST00000321505; = p.R1792* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 37/79 reads (47%) | catalogued as rs1395121822, COSV58585660; called by muse, mutect2
- KLK5 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs752873684; called by muse, mutect2, varscan2
- KRT13 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs764004897, COSV99877135; called by muse, mutect2, varscan2
- KRT6A | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs367788212; called by muse, mutect2, varscan2
- LHCGR | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 192/412 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs201964457; called by muse, mutect2, varscan2
- LRRC38 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs372230880, COSV65791462; called by muse, mutect2, varscan2
- NECTIN1 | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs150020241; called by muse, varscan2
- OR5AP2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs779510819, COSV57257212; called by muse, mutect2, varscan2
- OR6C74 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 143/271 reads (53%) | catalogued as COSV59606575, COSV59607250; called by muse, mutect2, varscan2
- RNF223 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.224); catalogued as rs1406395523; called by muse, mutect2, varscan2
- ROBO1 | c.4631G>A p.R1544Q | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.749); catalogued as rs760892507, COSV71396804, COSV71397952; called by muse, mutect2, varscan2
- SAFB2 | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759936375; called by muse, mutect2, varscan2
- SDK2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); catalogued as rs554956497; called by muse, mutect2, varscan2
- ST8SIA2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | PolyPhen possibly damaging (0.731); catalogued as rs527718623, COSV51568842; called by muse, mutect2, varscan2
- TENT5C | c.477_479del p.N159del | In Frame Del (DEL) | VAF 43/98 reads (44%) | catalogued as rs1403919133; called by pindel, varscan2
- TRAF3 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV61027720; called by muse, mutect2, varscan2
- UNC45A | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879160076; called by muse, mutect2, varscan2
- USP34 | c.7062C>A p.D2354E | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as rs866547962; called by muse, mutect2, varscan2
- ACTB | c.89T>A p.V30D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.1127G>T p.R376M (on ENST00000506720 / NM_001322402.2; = p.R308M on NM_015236.6) | Missense Mutation (SNP) | VAF 128/291 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDOA | c.263A>G p.D88G (on ENST00000642816 / NM_001243177.4; = p.D34G on NM_184041.5) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASPRV1 | c.604_613del p.I202Cfs*3 | Frame Shift Del (DEL) | VAF 74/413 reads (18%) | called by mutect2, pindel, varscan2
- ASPRV1 | c.145del p.T49Lfs*11 | Frame Shift Del (DEL) | VAF 43/182 reads (24%) | called by mutect2, varscan2
- B4GALNT4 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- CA9 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CACNA1G | c.204C>G p.S68R | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CAMTA1 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNE2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP74 | c.3878A>G p.H1293R | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CIBAR2 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CLEC4G | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- COL4A1 | c.4631T>A p.F1544Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- COPG1 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- DACH1 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DNAH8 | c.9003C>A p.C3001* | Nonsense Mutation (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- DNER | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DOCK1 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2
- EFR3B | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ETFB | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- FAM120B | c.1871C>A p.P624H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM184B | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FBXL13 | c.121dup p.M41Nfs*32 | Frame Shift Ins (INS) | VAF 51/167 reads (31%) | called by mutect2, pindel, varscan2
- GLB1L3 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- HABP2 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- IKZF4 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- KCTD4 | c.228T>G p.H76Q | Missense Mutation (SNP) | VAF 127/261 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LINC00922 | n.549C>A | Splice Region (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- MCM3AP | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC16 | c.2180T>C p.L727S | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- NLRP10 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NMRK2 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NR2F2 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- NR2F2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- OGFOD3 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10AG1 | c.749A>T p.Y250F | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OTOA | c.1482G>C p.Q494H (on ENST00000286149; = p.Q480H on NM_144672.4) | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PAPPA2 | c.4320G>A p.M1440I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- PARK7 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATZ1 | c.1336-1G>A p.X446_splice | Splice Site (SNP) | VAF 65/146 reads (45%) | called by muse, mutect2, varscan2
- PPP1R3F | c.1474T>A p.Y492N | Missense Mutation (SNP) | VAF 58/59 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PPP2R3A | c.2406C>G p.I802M | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PRDM1 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCD | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PROX1 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRR5L | c.1107A>T p.*369Cext*25 | Nonstop Mutation (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- PSEN1 | c.628del p.M210* | Frame Shift Del (DEL) | VAF 58/87 reads (67%) | called by mutect2, pindel, varscan2
- REX1BD | c.182+1G>T p.X61_splice | Splice Site (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- RYR1 | c.11299G>T p.A3767S | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMC4 | c.2609A>G p.Y870C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TBX5 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 150/313 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 67/166 reads (40%) | called by mutect2, pindel, varscan2
- TMEM221 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- TRAF3 | c.1567A>T p.K523* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- TRPV5 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMODL1 | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC5D | c.2702T>G p.I901S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF804A | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANKFY1 | c.1911C>T p.S637= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs371087594; called by muse, mutect2, varscan2
- ARID2 | c.2802A>G p.Q934= | Silent (SNP) | VAF 125/273 reads (46%) | catalogued as rs1436039372, COSV57596135; called by muse, mutect2, varscan2
- CACNA1E | c.3696C>T p.G1232= | Silent (SNP) | VAF 114/177 reads (64%) | catalogued as rs755064825, COSV62385177, COSV62399469; called by muse, mutect2, varscan2
- CAMK2B | c.1497T>C p.S499= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2
- CARD11 | c.2554C>A p.R852= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1445038476; called by muse, mutect2, varscan2
- COL22A1 | c.633C>T p.G211= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- DYRK1A | c.1473T>C p.N491= | Silent (SNP) | VAF 82/168 reads (49%) | called by muse, mutect2, varscan2
- FAM209B | c.435C>T p.L145= | Silent (SNP) | VAF 68/137 reads (50%) | called by muse, mutect2, varscan2
- GRAMD2B | c.1029T>G p.L343= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- HMCN2 | c.11511C>T p.G3837= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs1021731092; called by muse, mutect2, varscan2
- IGLL5 | c.57T>C p.G19= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs1372676421; called by muse, mutect2, varscan2
- IRX1 | c.1026C>T p.G342= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV57361951; called by muse, mutect2, varscan2
- KCNH8 | c.1800A>G p.K600= | Silent (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- MGMT | c.459C>T p.G153= (on ENST00000306010; = p.G122= on NM_002412.5) | Silent (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- MYO16 | c.5362C>T p.L1788= | Silent (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- NEB | c.4266G>A p.E1422= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as rs903379029; called by muse, mutect2, varscan2
- NPY1R | c.114C>T p.A38= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as rs1276791111; called by muse, mutect2
- SLC2A6 | c.12G>C p.P4= | Silent (SNP) | VAF 42/59 reads (71%) | called by muse, mutect2, varscan2
- SLC4A3 | c.2409C>T p.F803= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs754210504, COSV56094639; called by muse, mutect2, varscan2
- SYCP1 | c.2097T>C p.I699= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs1218455526; called by muse, mutect2, varscan2
- THSD7B | c.4587G>T p.G1529= (on ENST00000272643; = p.G1527= on NM_001316349.2) | Silent (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- AC097533.1 | n.242del | RNA (DEL) | VAF 38/91 reads (42%) | catalogued as rs778403564; called by mutect2, pindel, varscan2
- ACAD8 | c.1196-916del | Intron (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- CCDC12 | c.-87C>T | 5'UTR (SNP) | VAF 88/217 reads (41%) | catalogued as rs1173434976; called by muse, mutect2, varscan2
- CHRFAM7A | c.*763A>G | 3'UTR (SNP) | VAF 40/58 reads (69%) | called by muse, mutect2, varscan2
- CLEC5A | c.*221G>A | 3'UTR (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- CNPY1 | c.*1689T>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- DLL4 | c.*535G>A | 3'UTR (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- DPP10 | c.*266T>A | 3'UTR (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- DSG4 | c.*294A>T | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- DTX1 | c.-417C>G | 5'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- EGFR | c.*5716C>T | 3'UTR (SNP) | VAF 37/91 reads (41%) | catalogued as rs968054342; called by muse, mutect2, varscan2
- FAM189A2 | c.*337C>T | 3'UTR (SNP) | VAF 74/229 reads (32%) | called by muse, mutect2, varscan2
- FGFR2 | c.748+337G>A | Intron (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- FHDC1 | c.-64A>T | 5'UTR (SNP) | VAF 140/284 reads (49%) | called by muse, mutect2, varscan2
- GATA4 | chr8:11762559 A>T | 3'Flank (SNP) | VAF 12/15 reads (80%) | called by muse, varscan2
- GPR83 | c.*2043G>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as rs1565181995; called by muse, mutect2, varscan2
- GRIN3A | c.*229A>T | 3'UTR (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- GSAP | c.1766-369G>A | Intron (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- HRH1 | c.*1617G>A | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- IFNLR1 | c.*2679G>A | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- JARID2 | c.*618G>A | 3'UTR (SNP) | VAF 10/153 reads (7%) | catalogued as rs575394250; called by muse, mutect2
- LINC01546 | n.528G>T | RNA (SNP) | VAF 52/72 reads (72%) | catalogued as rs1326696738; called by muse, mutect2, varscan2
- LIPE | c.883+1539G>A | Intron (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- LSM5 | c.*359G>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- LTBP4 | c.2759-72G>A | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- MASP1 | c.*1910del | 3'UTR (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- MFNG | c.-44T>C | 5'UTR (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- MIR1972-2 | chr16:70034292 G>A | 3'Flank (SNP) | VAF 75/224 reads (33%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851306 A>G | 5'Flank (SNP) | VAF 92/101 reads (91%) | called by muse, varscan2
- MIR5195 | chr14:106851416 A>G | 5'Flank (SNP) | VAF 62/68 reads (91%) | called by muse, varscan2
- MMP16 | c.*6651G>T | 3'UTR (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- NDUFB2 | c.99-981A>G | Intron (SNP) | VAF 14/79 reads (18%) | called by muse, varscan2
- NKX2-5 | chr5:173235207 G>C | 5'Flank (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- NPNT | c.-1C>A | 5'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- NUP98 | c.*995C>T | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- OSBP | c.*1949C>T | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- P2RY13 | c.*1330C>T | 3'UTR (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- PGM2L1 | c.*3378dup | 3'UTR (INS) | VAF 24/70 reads (34%) | catalogued as rs1276144876; called by mutect2, varscan2
- PLAG1 | c.*2455C>T | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- PLCB1 | c.384+76G>A | Intron (SNP) | VAF 18/31 reads (58%) | catalogued as COSV62038671; called by muse, mutect2, varscan2
- PMEPA1 | c.*1382C>T | 3'UTR (SNP) | VAF 68/120 reads (57%) | catalogued as rs1019205554; called by muse, mutect2, varscan2
- POFUT1 | c.*3962G>T | 3'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- PPP1R12C | c.322-695A>G | Intron (SNP) | VAF 49/84 reads (58%) | called by muse, mutect2, varscan2
- PRKAR2A | c.*1572C>G | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- PTPN9 | c.-92C>G | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- RAB3C | c.*406_*408del | 3'UTR (DEL) | VAF 5/25 reads (20%) | called by muse*, mutect2
- RBM7 | c.438+424G>C | Intron (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- RFLNB | c.*1340A>G | 3'UTR (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- RIMBP2 | c.*1543T>A | 3'UTR (SNP) | VAF 55/158 reads (35%) | called by muse, mutect2, varscan2
- ROBO2 | c.-27A>C | 5'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- RTKN2 | c.*1741T>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- SACM1L | c.*1080_*1081del | 3'UTR (DEL) | VAF 22/58 reads (38%) | catalogued as rs1223369511; called by pindel, varscan2
- SCARA5 | c.1153+250C>T | Intron (SNP) | VAF 36/49 reads (73%) | called by muse, mutect2, varscan2
- SERPINB5 | c.*1205G>T | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- SLC35F3 | c.*398T>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- SLC35G3 | c.*589A>C | 3'UTR (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- SLF2 | c.2042+455C>T | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- SNORA26 | chr4:52712808 C>T | 5'Flank (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- SNORA72 | chr1:224175481 C>T | 5'Flank (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- SNRK | c.*2125T>C | 3'UTR (SNP) | VAF 47/82 reads (57%) | catalogued as rs949172166; called by muse, mutect2, varscan2
- SORL1 | c.*4018C>T | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- STAB1 | c.*2G>C | 3'UTR (SNP) | VAF 121/257 reads (47%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3090+64T>C | Intron (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- SUCLA2 | c.*371A>G | 3'UTR (SNP) | VAF 10/25 reads (40%) | catalogued as rs1440020678; called by muse, mutect2, varscan2
- SUSD4 | c.*1014C>T | 3'UTR (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975604 C>T | 5'Flank (SNP) | VAF 126/136 reads (93%) | catalogued as COSV66082081; called by muse, mutect2, varscan2
- TRAF3IP2 | chr6:111556944 T>C | 3'Flank (SNP) | VAF 6/9 reads (67%) | catalogued as rs1032970635; called by mutect2, varscan2
- TRAPPC6A | c.*147G>A | 3'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, varscan2
- TTN | c.10360+3559G>T | Intron (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- TXNIP | c.*225G>C | 3'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*3430A>G | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- ZNF207 | c.*8851C>T | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- ZNF33A | c.*2506A>T | 3'UTR (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- ZNF462 | c.*949T>A | 3'UTR (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
